Gene-level copy-number profile of tumor specimen TCGA-GS-A9TQ-01A from TCGA case TCGA-GS-A9TQ, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of inguinal region or leg; Age at diagnosis: 69.2 years (25,292 days).
Specimen TCGA-GS-A9TQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-DLBC.ea3db49a-7294-4964-8bb5-96500ea47958.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GS-A9TQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d16cbcf4-526d-4fa1-8a5d-4059ba38f231

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 2: 5,115; copy number 3: 18,904; copy number 4: 18,868; copy number 5: 4,716; copy number 6: 8,276; copy number 7: 1,718; copy number 8: 729; copy number 9: 1,321; copy number 10: 74; copy number 12: 78.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GS-A9TQ-01A-11D-A381-01): tumor purity 0.74, ploidy 3.92, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–3): MTAP, AL359922.1.
- chr9:21,858,910–22,128,103, 11 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,920 genes in 39 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:51,925,692–64,252,859, 191 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr3:187,796,187–189,325,304, 15 genes, copy number 10: AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2, LPP, FLJ42393, LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2.
- chr3:191,329,085–192,119,864, 8 genes, copy number 10 (within-gene range 4–10): CCDC50, AC073365.1, PYDC2, Y_RNA, AC026320.2, AC026320.1, AC026320.3, RN7SKP222.
- chr3:192,238,037–192,283,097, 1 gene, copy number 10: FGF12-AS1.
- chr3:194,471,923–198,222,513, 142 genes, copy number 9 (broad region; genes not listed).
- chr6:167,607–58,438,364, 1,527 genes, copy number 7 (broad region; genes not listed).
- chr7:64,045,429–65,006,743, 55 genes, copy number 9 (within-gene range 6–9): AC115220.1, ZNF727, TRIM60P17, GUSBP6, MTND4P2, MTND4LP2, MTND3P2, MTCO3P8, MTATP6P18, MTCO2P8, MTCO1P8, MTND2P4, MTND1P2, AC091685.1, AC091685.2, VN1R37P, VN1R38P, SAPCD2P1, ZNF735, ZNF679, AC073270.1, ZNF736, TRIM60P18, AC073270.2, AC022202.1, YWHAEP1, VN1R40P, ZNF680P1, HNRNPCP7, ZNF680, BNIP3P42, AC016769.3, AC016769.1, AC016769.2, AC016769.4, AC016769.5, AC016769.6, ZNF107, BNIP3P11, MIR6839, AC091799.1, AC073349.3, ZNF138, AC073349.4, AC073349.2, SEPHS1P1, EEF1DP4, AC073349.5, ZNF273, AC073349.1, VN1R42P, MTDHP1, AC073210.3, ZNF117, ERV3-1.
- chr7:68,020,235–68,319,676, 6 genes, copy number 8: AC092637.1, AC006013.1, MTCO1P57, AC093655.1, AC093655.2, MTND4P3.
- chr7:68,723,911–110,534,757, 762 genes, copy number 8–9 (within-gene range 3–9) (broad region; genes not listed).
- chr8:150,584–2,728,577, 54 genes, copy number 8 (within-gene range 3–8): AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2.
- chr8:6,036,433–8,199,973, 118 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr8:9,136,255–12,388,296, 112 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr8:19,084,992–19,758,029, 10 genes, copy number 8 (within-gene range 3–8): AC100849.1, AC100849.2, AC068880.1, AC068880.3, AC068880.2, AC068880.5, SH2D4A, AC068880.4, CSGALNACT1, AC090541.1.
- chr8:32,440,704–36,779,209, 50 genes, copy number 9 (within-gene range 3–9): NRG1-IT3, AC083977.1, RNU6-663P, AC090204.1, MTND1P6, MTND2P32, RANP9, AC104027.1, RNU6-528P, AC067838.1, FUT10, AC091144.2, TTI2, MAK16, SNORD13, AC091144.1, SNORA70, RPL10P18, RNF122, RN7SL621P, DUSP26, AF279873.3, BUD31P1, RN7SL457P, VENTXP5, AF279873.2, AF279873.1, AF279873.4, AC087855.2, AC090993.1, AC087855.1, RPL10AP3, LINC01288, AC087343.1, AC099685.1, UNC5D, AC090740.1, LSM12P1, AC105230.1, AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10.
- chr8:41,803,349–43,131,180, 36 genes, copy number 8 (within-gene range 3–8): Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P, POMK.
- chr8:43,672,823–47,736,306, 37 genes, copy number 8 (within-gene range 3–8): AC139365.2, AC139365.1, AC118650.1, HSPA8P13, ASNSP1, AC104576.1, ASNSP4, AC021451.1, TRIM60P15, AC021451.2, AC021451.3, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32, AC120036.1, AC120036.5, RNU6-819P, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1, SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3.
- chr8:49,330,210–49,907,446, 7 genes, copy number 9: RN7SKP294, RFPL4AP7, AC090155.2, AC090155.1, PSAT1P1, AC113145.1, AC023762.1.
- chr8:50,762,460–52,745,843, 22 genes, copy number 9: CYCSP22, AC087272.1, AC090919.1, AC012413.1, PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1, RB1CC1, AC113139.1.
- chr8:53,162,339–53,390,872, 4 genes, copy number 9: AC009646.1, AC009646.2, OPRK1, AC131902.1.
- chr8:55,102,028–55,542,054, 1 gene, copy number 8 (within-gene range 3–8): XKR4.
- chr8:55,449,509–55,455,139, 1 gene, copy number 8: SBF1P1.
- chr8:55,696,424–58,272,450, 52 genes, copy number 8: TMEM68, RNA5SP265, TGS1, LYN, AC018607.1, SNORA1B, RN7SL798P, RN7SL323P, AC046176.1, RPS20, SNORD54, CERNA3, NPM1P21, MOS, AC107376.1, PLAG1, CHCHD7, AC107952.2, AC107952.1, SDR16C5, SDR16C6P, PENK, AC012349.1, SEPTIN10P1, LINC00968, AC013644.1, RPL37P6, AC009597.1, AC009597.2, RNU6-13P, BPNT2, RNA5SP266, LINC01606, AC025674.1, AC025674.2, LINC00588, RNU6-596P, AC068075.1, RPL30P10, AC068075.2, AC090796.1, AC104051.1, AC104051.2, LINC01602, AC012103.1, FAM110B, AC104350.1, AC027698.1, RPL26P26, AC092819.3, AC092819.1, AC092819.2.
- chr8:66,964,099–67,056,604, 1 gene, copy number 9 (within-gene range 3–9): PPP1R42.
- chr8:67,043,079–70,485,687, 51 genes, copy number 9 (within-gene range 3–9): COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1, NDUFS5P6, PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1, LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P.
- chr8:77,399,072–82,961,926, 86 genes, copy number 9 (within-gene range 3–9) (broad region; genes not listed).
- chr8:83,912,713–84,949,674, 9 genes, copy number 9: AC015522.1, TPM3P3, AC012400.1, RALYL, RNU6-1040P, PSMC2P2, AC009901.1, AC009901.2, ACTBP6.
- chr8:87,788,562–88,019,113, 4 genes, copy number 9: SOX5P1, AC005066.1, DCAF4L2, AC037450.1.
- chr8:90,198,389–90,687,863, 4 genes, copy number 9 (within-gene range 3–9): AC004083.1, LINC00534, RNA5SP273, LINC01030.
- chr8:90,646,420–90,670,929, 1 gene, copy number 9: AC106038.1.
- chr8:97,132,835–100,663,415, 76 genes, copy number 8 (broad region; genes not listed).
- chr8:102,621,509–105,804,539, 53 genes, copy number 8 (within-gene range 3–8): POU5F1P2, KLF10, AP002851.1, ADI1P2, GASAL1, AZIN1, AP003696.1, MAILR, AP003354.1, RPL5P24, Y_RNA, NPM1P52, AP003550.1, ATP6V1C1, MTND1P5, MTCO1P4, MTCO2P4, LINC01181, BAALC-AS2, BAALC, BAALC-AS1, MIR3151, AC025370.1, FZD6, AC025370.2, CTHRC1, AC012213.3, RNU6-1011P, SLC25A32, AC012213.5, DCAF13, AC012213.2, AC012213.4, AC012213.1, RIMS2, PTMAP15, AC007751.1, AC090686.1, DPYS, DCSTAMP, AP003471.1, AP002847.1, MIR548A3, LRP12, NDUFA5P2, ZFPM2, AC012564.1, AC090142.2, AC090142.3, AC090142.1, AC021546.1, TMCC1P1, AC041039.1.
- chr8:105,662,352–105,685,765, 2 genes, copy number 8: AC103853.1, AC103853.2.
- chr8:107,249,482–120,542,133, 113 genes, copy number 9–12 (within-gene range 6–12) (broad region; genes not listed).
- chr8:125,091,679–128,187,101, 45 genes, copy number 10 (within-gene range 4–10): NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1, AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P.
- chr8:128,323,131–131,144,948, 31 genes, copy number 9: AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, AC103718.1, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1, ADCY8, AC103726.1, AC103726.2, AC087341.1.
- chr8:134,190,383–134,979,279, 18 genes, copy number 9 (within-gene range 4–9): AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56.
- chr8:137,105,352–137,698,467, 4 genes, copy number 10: RNU6-144P, ZYXP1, AC105213.1, AC110053.1.
- chr8:137,852,204–138,019,873, 1 gene, copy number 10 (within-gene range 4–10): AC046195.2.
- chr8:139,460,062–145,066,685, 210 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
